Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H2-01A (Primary Tumor).

Surgical Pathology

CASE NUMBER:

DIAGNOSIS:

ADRENAL, RIGHT (EXCISION): PHEOCHROMOCYTOMA, SEE NOTE.

NOTE:

CHROMOGRANIN STAINING IS POSITIVE. S-100 STAINS SUSTENTACULAR CELLS.

CLINICAL INFORMATION: HISTORY: RIGHT ADRENAL MASS ORDERING PROTOCOL:

PROCEDURE: PREOP DX: #R ADRENAL MASS POSTOP DX: R ADRENAL MASS OPERATIVE FINDINGS: R ADRENAL MASS

SPECIMENS SUBMITTED: ADRENAL MASS, RIGHT

GROSS DESCRIPTION:

THE SPECIMEN IS RECEIVED IN FRESH IN A CONTAINER LABELED "RIGHT ADRENAL - PHEOCHROMOCYTOMA". IT CONSISTS OF A 5 X 4.5 X 2.5, 35.3 GRAM SOFT TISSUE FRAGMENT. BIVALVING OF THE SPECIMEN REVEALS A SOFT, FLESHY, TAN TUMOR TISSUE WITH MULTIPLE FOCI OF HEMORRHAGE, MEASURING 4 CM. IN THE LARGEST DIMENSION. A 4 X 2 X 1 CM. FRAGMENT OF TUMOR WAS PROCURED BY THE UOB LABORATORY FOR THE PROTOCOL. THE REMAINDER OF THE SPECIMEN WAS SUBMITTED FOR ROUTINE PROCESSING. THE SPECIMEN IS RECEIVED IN SURGICAL PATHOLOGY AFTER PROCUREMENT. THE SPECIMEN IS INKED BLACK AVOIDING THE CUT SURFACE, AND REPRESENTATIVE SECTIONS ARE SUBMITTED FOR PERMANENT IN CASSETTES A-H.

Requested By:

Do not file in Medical Record

	Yes	No
Critera		
Diagnostic Discrepancy		
HPA Discrepancy		
Clonal/Synchronous/Recurrent		
Case is (title):		

hw 5/23/13

5/23/13

Source: NCI Genomic Data Commons file 1f902ea4-7ddc-456d-bf0f-0360b526dc63 (TCGA-QR-A6H2.7CFFCD18-BB7B-4B9C-9440-C7B33BFC970B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).